Gene-level copy-number profile of tumor specimen TCGA-GU-A42P-01A from TCGA case TCGA-GU-A42P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,546 days).
Specimen TCGA-GU-A42P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ebbe3514-5a25-4c7b-9932-3b288cfe7ca1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-A42P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63de706a-b2ad-44b9-b9a4-2bc39ec5d7a7

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,387; copy number 3: 1,794; copy number 4: 14,523; copy number 5: 18,944; copy number 6: 11,798; copy number 7: 5,684; copy number 8: 3,154; copy number 9: 963; copy number 10: 305; copy number 11: 195; copy number 12: 14; copy number 13: 19; copy number 14: 14; copy number 15: 17; copy number 22: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-A42P-01A-11D-A23T-01): tumor purity 0.8, ploidy 5.31, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 268 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:21,233,168–23,125,087, 20 genes, copy number 11–14: AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P.
- chr6:60,719,222–62,286,225, 10 genes, copy number 11 (within-gene range 5–11): GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr7:30,027,404–31,111,479, 35 genes, copy number 11 (within-gene range 6–11): PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1.
- chr7:63,924,787–64,037,958, 13 genes, copy number 12: AC092634.3, AC092634.8, SLC25A1P3, VN1R34P, ARAFP1, AC092634.7, VN1R35P, VN1R36P, AC092634.1, AC092634.6, ZNF722P, LINC01005, AC115220.2.
- chr7:64,045,434–64,085,339, 1 gene, copy number 12 (within-gene range 5–12): ZNF727.
- chr17:39,665,349–41,930,542, 153 genes, copy number 11–22 (within-gene range 10–22) (broad region; genes not listed).
- chr18:6,729,716–6,915,716, 1 gene, copy number 13 (within-gene range 6–13): ARHGAP28.
- chr18:6,873,399–9,020,764, 35 genes, copy number 13–15: AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
